Surgical pathology report (de-identified scan), TCGA case TCGA-HT-8019, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-8019-01A (Primary Tumor).

Pathology Report for [REDACTED]

Addendum Discussion:

The MIB-1 labeling index ranges up to 18.8%. The elevated MIB-1 labeling index is concerning for early anaplastic progression in an otherwise histologically low grade tumor.

Addendum Diagnosis:

Oligodendroglioma grade III with elevated MIB-1 labeling index consistent with early anaplastic progression.

- MIB-1 labeling index: 18.8%

Microscopic Description:

Sections demonstrate a mildly to moderately hypercellular glial neoplasm that diffusely infiltrates both gray and white matter. Perineural satellitosis is seen. The tumor cells have round mildly atypical nuclei that are somewhat opened with a small nucleolus. Perinuclear halos are prominent. There is little atypia. Mitotic figures are not seen. There is no microvascular proliferation or necrosis.

Source: NCI Genomic Data Commons file a733d585-84de-4a61-98a5-19a86afe7193 (TCGA-HT-8019.18EBA3FF-F941-4A98-8603-E40CE199AA27.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).